Somatic mutation profile of tumor specimen TCGA-QH-A65R-01A (aliquot TCGA-QH-A65R-01A-21D-A31L-08) from TCGA case TCGA-QH-A65R, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 38.5 years (14,073 days).
Specimen TCGA-QH-A65R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) feb92bc0-4703-4cf2-9270-4a92c496ab76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A65R-10A (Blood Derived Normal), aliquot TCGA-QH-A65R-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba43b85e-5dae-464b-b1fd-a85eed7aecf8

The open-access MAF lists 32 somatic variants for this specimen: 27 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 24, Silent 5, Frame Shift Del 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC100868.1 | c.932G>A p.S311N | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV51847075; called by muse, mutect2, varscan2
- ATP4A | c.2173G>A p.V725I | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs767066130, COSV52871066; called by muse, mutect2
- BCL11B | c.1859G>A p.R620H (on ENST00000357195 / NM_001282237.2; = p.R549H on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV100596031; called by muse, mutect2
- CD1A | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.412); catalogued as rs200394336, COSV56860405, COSV99192484; called by muse, mutect2, varscan2
- DNAJC21 | c.591A>C p.K197N | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100331632; called by muse, mutect2
- EPPK1 | c.5354G>A p.R1785H | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs189786019, COSV73261399, COSV73262293; called by muse, mutect2
- FAAP100 | c.1891G>A p.V631I | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs755141804, COSV100585646; called by muse, mutect2, varscan2
- GAPVD1 | c.3167C>G p.T1056R (on ENST00000394104; = p.T1083R on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99783930; called by muse, mutect2, varscan2
- H2BW1 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs782108956, COSV54220097, COSV54220903; called by muse, mutect2, varscan2
- LRBA | c.7246G>T p.V2416F | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100842195; called by muse, mutect2, varscan2
- MICAL1 | c.3160C>T p.R1054C | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs764409138, COSV99238143; called by muse, mutect2, varscan2
- MYH8 | c.4259C>T p.T1420M | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs150344258; called by mutect2, varscan2
- NRP1 | c.2047A>G p.I683V | Missense Mutation (SNP) | VAF 120/332 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as COSV99589817; called by muse, mutect2, varscan2
- PPP1R26 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760721442, COSV63356701; called by muse, mutect2, varscan2
- PRF1 | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs911803198, COSV100942709, COSV64615446; called by muse, mutect2, varscan2
- PTDSS1 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.572); catalogued as rs746427419, COSV100428539, COSV100429013; called by muse, mutect2, varscan2
- STAT5A | c.98A>G p.Y33C | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV100604880, COSV61808648; called by muse, mutect2, varscan2
- TENM1 | c.6767G>A p.R2256H | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100951296; called by muse, mutect2, varscan2
- TLR1 | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100458759; called by muse, mutect2, varscan2
- TP53RK | c.587A>G p.K196R | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100927791; called by muse, mutect2, varscan2
- UPF3B | c.389T>A p.I130K | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99352443; called by muse, mutect2, varscan2
- ZBED2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs758268672, COSV51912916; called by muse, mutect2, varscan2
- ZBTB20 | c.1862T>A p.L621H (on ENST00000474710 / NM_001164342.2; = p.L548H on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100615511; called by muse, mutect2, varscan2
- FRY | c.5461_5462del p.K1821Efs*3 | Frame Shift Del (DEL) | VAF 8/57 reads (14%) | called by mutect2, pindel, varscan2
- MMP10 | c.159_162del p.K54Tfs*20 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel, varscan2
- SLCO4C1 | c.1276del p.A426Lfs*3 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | called by mutect2, pindel, varscan2
- ANKRD17 | c.7314T>G p.T2438= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV100430147; called by muse, mutect2, varscan2
- BPTF | c.7221C>T p.P2407= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100076335; called by muse, mutect2, varscan2
- LGR6 | c.2734C>T p.L912= (on ENST00000367278 / NM_001017403.1; = p.L860= on NM_021636.3) | Silent (SNP) | VAF 39/111 reads (35%) | catalogued as COSV99708096; called by muse, mutect2, varscan2
- USP4 | c.2181A>T p.G727= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as COSV99649877; called by muse, mutect2, varscan2
- WHRN | c.198C>T p.H66= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV54328032; called by muse, mutect2, varscan2
